Somatic mutation profile of tumor specimen ALCH-ADPR-TTP1-A (aliquot ALCH-ADPR-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADPR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,223 days).
Specimen ALCH-ADPR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8e1774c-4589-42d9-843c-b56136afbb87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADPR-NB1-A (Blood Derived Normal), aliquot ALCH-ADPR-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f9f8904-8546-439e-acc7-63fcfbbd9664

The open-access MAF lists 193 somatic variants for this specimen: 141 protein-altering or splice-affecting, 36 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 36, Nonsense Mutation 13, Splice Region 4, 3'UTR 4, Splice Site 4, Frame Shift Del 4, Intron 3, RNA 3, 5'Flank 2, 3'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 176/876 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRL2 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780393998; called by muse, mutect2, varscan2
- AL121899.2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67350871; called by muse, mutect2
- ASTN2 | c.2464G>T p.E822* (on ENST00000313400 / NM_001365069.1; = p.E771* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 21/161 reads (13%) | catalogued as COSV57814546; called by muse, mutect2, varscan2
- ATM | c.4667A>G p.Y1556C | Missense Mutation (SNP) | VAF 87/429 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as rs587782037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS12 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752062702; called by muse, mutect2, varscan2
- CEMIP2 | c.1617G>T p.M539I | Missense Mutation (SNP) | VAF 78/579 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100987331; called by muse, mutect2, varscan2
- CHMP5 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 67/627 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290077900; called by muse, mutect2, varscan2
- COL15A1 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745493353; called by mutect2, varscan2
- COL1A2 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.473); catalogued as rs1277668852; called by muse, mutect2, varscan2
- COL4A1 | c.3821C>T p.P1274L | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101011344; called by muse, mutect2, varscan2
- COL4A3 | c.2656+4T>A | Splice Region (SNP) | VAF 141/964 reads (15%) | catalogued as rs779293980; called by muse, mutect2, varscan2
- CPB2 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756021492, COSV51675131; called by muse, mutect2, varscan2
- CSMD1 | c.2261G>A p.R754H (on ENST00000520002; = p.R753H on NM_033225.6) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs748646070, COSV100148839, COSV59366434; called by muse, mutect2, varscan2
- CSMD3 | c.5409G>T p.Q1803H (on ENST00000297405 / NM_001363185.1; = p.Q1699H on NM_052900.3) | Missense Mutation (SNP) | VAF 146/948 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52311358; called by muse, mutect2, varscan2
- DNAAF4 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 102/617 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1322169594; called by muse, mutect2, varscan2
- EPPK1 | c.6691G>A p.V2231M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101599800; called by muse, varscan2
- FAM47A | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs369143353, COSV60493587; called by muse, mutect2, varscan2
- FOXN1 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs765915993; called by muse, mutect2, varscan2
- GOLGA6B | c.1782G>C p.Q594H | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV69770161; called by muse, mutect2
- GOPC | c.1325C>A p.P442Q | Missense Mutation (SNP) | VAF 179/1028 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.346); catalogued as COSV50002522; called by muse, mutect2, varscan2
- GRIK2 | c.2573del p.C858Lfs*5 | Frame Shift Del (DEL) | VAF 34/190 reads (18%) | catalogued as COSV59759742; called by mutect2, pindel, varscan2
- HHIP | c.1024T>G p.F342V | Missense Mutation (SNP) | VAF 39/1052 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs1560713883, COSV99667569; called by muse, mutect2
- HTR1E | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59511240; called by muse, mutect2, varscan2
- IRX2 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs1403039474; called by muse, mutect2
- KCNA10 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63904974; called by muse, mutect2, varscan2
- KIR3DX1 | n.75C>A | Splice Region (SNP) | VAF 32/292 reads (11%) | catalogued as rs776938727, COSV55597451; called by muse, mutect2, varscan2
- MACROH2A1 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56893003; called by muse, mutect2, varscan2
- MNS1 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 94/513 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1199287113; called by muse, mutect2, varscan2
- MYO1A | c.2149T>C p.Y717H | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs754897671; called by muse, mutect2, varscan2
- NDST4 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52118736, COSV52137899; called by muse, mutect2, varscan2
- NPY5R | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 67/435 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV58451956; called by muse, mutect2, varscan2
- OR2F2 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747660686, COSV68832720; called by muse, mutect2, varscan2
- OR4D1 | c.548A>T p.Q183L | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV52125608; called by muse, mutect2, varscan2
- PCDH17 | c.1860C>G p.S620R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1019580612, COSV100931786, COSV64976441; called by muse, mutect2, varscan2
- PCDH8 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.635); catalogued as rs1387478819; called by muse, mutect2
- PCDHB7 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV50761582; called by muse, mutect2, varscan2
- PCDHGA3 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); catalogued as COSV53899063; called by muse, mutect2, varscan2
- PEG10 | c.547G>T p.D183Y (on ENST00000482108 / NM_001040152.2; = p.D217Y on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV71788082; called by muse, mutect2, varscan2
- PRDM9 | c.2312C>A p.T771K | Missense Mutation (SNP) | VAF 159/600 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs766263099; called by muse, varscan2
- RAB3GAP2 | c.1515G>T p.M505I | Missense Mutation (SNP) | VAF 105/841 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV62784296; called by muse, mutect2, varscan2
- RBM46 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV55980904; called by muse, mutect2, varscan2
- RYR3 | c.4495C>T p.L1499F | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.685); catalogued as rs757410936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK3 | c.1653G>T p.L551F | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53845296; called by muse, mutect2, varscan2
- TAF1L | c.3412C>T p.R1138C | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.582); catalogued as rs754012773, COSV54260556; called by muse, mutect2, varscan2
- THBS4 | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 94/639 reads (15%) | catalogued as rs1388692425; called by muse, mutect2, varscan2
- WDR41 | c.442T>C p.W148R | Missense Mutation (SNP) | VAF 93/637 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs748863748; called by muse, mutect2, varscan2
- ZC3H12C | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 96/581 reads (17%) | catalogued as COSV53706748, COSV53707432; called by muse, mutect2, varscan2
- ZNF490 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100267211; called by muse, mutect2, varscan2
- ADAMTS6 | c.2191+1G>T p.X731_splice | Splice Site (SNP) | VAF 30/144 reads (21%) | called by muse, varscan2
- ANKRD36C | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ANKRD49 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 99/667 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AP4E1 | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 146/841 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP15 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASH1L | c.5398G>T p.V1800L | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BTBD11 | c.1285A>T p.S429C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CAMK1D | c.487A>T p.I163F | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC168 | c.16999G>T p.G5667C | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC168 | c.14089T>G p.F4697V | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CCDC61 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CDC25C | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CEP295 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CLCN6 | c.707+4T>A | Splice Region (SNP) | VAF 22/451 reads (5%) | called by muse, mutect2
- COL11A1 | c.2877G>C p.K959N | Missense Mutation (SNP) | VAF 77/447 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- COL25A1 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 69/320 reads (22%) | called by muse, mutect2, varscan2
- COL6A2 | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.3437G>T p.R1146I (on ENST00000520002; = p.R1145I on NM_033225.6) | Missense Mutation (SNP) | VAF 83/377 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDR2 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DENND4B | c.3842A>T p.E1281V | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); called by muse, mutect2
- DGKB | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 94/505 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH14 | c.2374G>T p.A792S (on ENST00000445597; = p.A858S on NM_001367479.1) | Missense Mutation (SNP) | VAF 53/523 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPP2 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 136/478 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.4286G>T p.R1429I | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBRS | c.983C>T p.A328V (on ENST00000287468; = p.A848V on NM_001105079.3) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- FSIP2 | c.17010C>A p.H5670Q | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.17011C>A p.H5671N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GPR15 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2
- IGKV1-6 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KIF14 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 38/798 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- KIRREL1 | c.766A>T p.R256W | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIRREL2 | c.1956C>A p.C652* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- KIRREL2 | c.1957A>G p.R653G | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLHL1 | c.463T>A p.S155T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- KRT37 | c.610del p.E204Rfs*28 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- LALBA | c.366C>A p.Y122* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | called by muse, mutect2, varscan2
- MANBA | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 108/605 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MED20 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- METTL14 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 21/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYOM2 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NADSYN1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NFASC | c.2545G>A p.E849K (on ENST00000339876 / NM_001378329.1; = p.E952K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/481 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NLRP3 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NLRP8 | c.2518del p.Q840Sfs*7 | Frame Shift Del (DEL) | VAF 12/131 reads (9%) | called by mutect2, pindel
- NPAP1 | c.607dup p.C203Lfs*21 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- OCSTAMP | c.846G>T p.W282C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OR4M1 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- OR51V1 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.251); called by muse, mutect2
- PCDH15 | c.1814T>C p.V605A | Missense Mutation (SNP) | VAF 135/872 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PDE8A | c.571A>C p.M191L | Missense Mutation (SNP) | VAF 78/446 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKNOX2 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLXND1 | c.4690G>T p.G1564C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROM1 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 68/466 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRSS55 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PSG5 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PSG6 | c.751A>T p.R251W | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTP4A2 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 85/431 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- PUM3 | c.349A>T p.K117* | Nonsense Mutation (SNP) | VAF 106/706 reads (15%) | called by muse, mutect2, varscan2
- RIOK1 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPL5 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 142/691 reads (21%) | called by muse, mutect2, varscan2
- RYBP | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 164/962 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SELE | c.912C>A p.C304* | Nonsense Mutation (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- SETD1A | c.4885C>G p.H1629D | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SLX4 | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 85/482 reads (18%) | called by muse, mutect2, varscan2
- SNRNP200 | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- SNRNP200 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 61/370 reads (16%) | called by muse, mutect2, varscan2
- SOGA1 | c.3379G>C p.E1127Q | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- SRSF8 | c.630_635del p.K211_S212del | In Frame Del (DEL) | VAF 42/268 reads (16%) | called by mutect2, pindel, varscan2
- ST18 | c.2712G>T p.K904N | Missense Mutation (SNP) | VAF 81/418 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- STARD8 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, varscan2
- STEAP1 | c.939G>T p.L313F | Missense Mutation (SNP) | VAF 24/539 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- STK3 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 120/842 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TADA2A | c.605-1G>A p.X202_splice | Splice Site (SNP) | VAF 74/310 reads (24%) | called by muse, mutect2, varscan2
- TATDN1 | c.517-2A>T p.X173_splice | Splice Site (SNP) | VAF 60/320 reads (19%) | called by muse, mutect2, varscan2
- TBC1D1 | c.2321G>A p.W774* | Nonsense Mutation (SNP) | VAF 59/409 reads (14%) | called by muse, mutect2, varscan2
- TFAP2D | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 90/415 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM187 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TMPRSS15 | c.1154C>A p.T385N | Missense Mutation (SNP) | VAF 147/854 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPO | c.1754A>T p.D585V | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGV1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 35/484 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.046); called by muse, mutect2
- TRO | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- TUBA3C | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- UNC45A | c.855G>T p.V285= | Splice Region (SNP) | VAF 45/244 reads (18%) | called by muse, mutect2, varscan2
- UNC45A | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- USH2A | c.5314G>T p.G1772* | Nonsense Mutation (SNP) | VAF 144/597 reads (24%) | called by muse, mutect2, varscan2
- USP29 | c.1745del p.K582Sfs*2 | Frame Shift Del (DEL) | VAF 29/153 reads (19%) | called by mutect2, pindel, varscan2
- VPS13B | c.3135C>A p.S1045R | Missense Mutation (SNP) | VAF 76/1283 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ZFC3H1 | c.4745-1G>C p.X1582_splice | Splice Site (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- ZNF2 | c.386G>C p.G129A (on ENST00000611147 / NM_001291605.2; = p.G116A on NM_021088.4) | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ZNF208 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ZNF717 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- ZNF808 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.574); called by muse, mutect2
- ADAMTS1 | c.1926G>T p.A642= | Silent (SNP) | VAF 90/428 reads (21%) | called by muse, mutect2, varscan2
- AP1G2 | c.1192C>A p.R398= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- AS3MT | c.984G>A p.L328= | Silent (SNP) | VAF 57/440 reads (13%) | called by muse, mutect2, varscan2
- ASTN2 | c.795G>T p.R265= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV57793053; called by muse, mutect2, varscan2
- BAHCC1 | c.7761C>T p.T2587= | Silent (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- CTR9 | c.2517G>T p.R839= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2, varscan2
- DNAH3 | c.3708A>T p.P1236= | Silent (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- DNAH6 | c.4284G>T p.A1428= | Silent (SNP) | VAF 45/291 reads (15%) | catalogued as COSV52876225; called by muse, mutect2, varscan2
- ELFN2 | c.2199G>T p.P733= | Silent (SNP) | VAF 14/76 reads (18%) | called by muse, varscan2
- FAM177B | c.24G>A p.Q8= | Silent (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
- GAD2 | c.1203T>A p.P401= | Silent (SNP) | VAF 63/423 reads (15%) | called by muse, mutect2, varscan2
- GLG1 | c.1893G>T p.L631= | Silent (SNP) | VAF 81/288 reads (28%) | called by muse, mutect2, varscan2
- HERC2 | c.6222G>T p.V2074= | Silent (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2, varscan2
- HMGXB3 | c.3753C>A p.S1251= (on ENST00000613459; = p.S1005= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/311 reads (15%) | called by muse, mutect2, varscan2
- ITK | c.600G>A p.L200= | Silent (SNP) | VAF 84/486 reads (17%) | called by muse, mutect2, varscan2
- KCNK10 | c.141C>A p.S47= | Silent (SNP) | VAF 43/223 reads (19%) | called by muse, mutect2, varscan2
- KRTAP10-9 | c.306C>A p.P102= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV59965833; called by muse, mutect2, varscan2
- MTERF4 | c.258A>T p.V86= | Silent (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- MUC22 | c.396C>T p.T132= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- OCRL | c.1137C>T p.H379= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs1174468423, COSV63981385; called by muse, mutect2, varscan2
- OR2F2 | c.222C>A p.A74= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV101283808, COSV68832726; called by muse, mutect2, varscan2
- PES1 | c.1743G>A p.K581= | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1470C>A p.V490= | Silent (SNP) | VAF 150/808 reads (19%) | called by muse, varscan2
- RFX6 | c.1638G>A p.Q546= | Silent (SNP) | VAF 101/631 reads (16%) | called by muse, mutect2, varscan2
- SCYL3 | c.69A>G p.G23= | Silent (SNP) | VAF 102/887 reads (11%) | called by muse, mutect2, varscan2
- SEMA6D | c.2224C>T p.L742= (on ENST00000316364 / NM_153618.2; = p.L680= on NM_020858.2) | Silent (SNP) | VAF 51/333 reads (15%) | called by muse, mutect2, varscan2
- SHANK1 | c.3354C>A p.G1118= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1360819942; called by muse, mutect2
- SOBP | c.1095C>A p.S365= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs369691874; called by muse, mutect2, varscan2
- STARD9 | c.5589A>G p.T1863= | Silent (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- SYNE3 | c.1311G>T p.A437= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- TBC1D8 | c.711G>A p.L237= | Silent (SNP) | VAF 132/576 reads (23%) | catalogued as COSV100964305; called by muse, mutect2, varscan2
- TBX2 | c.822G>A p.L274= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- TMEM151A | c.735C>G p.A245= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- WT1 | c.351C>T p.G117= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1473590912; called by muse, mutect2, varscan2
- ZFP36L2 | c.813G>A p.P271= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1257627639; called by mutect2, varscan2
- ZNF490 | c.981T>A p.T327= | Silent (SNP) | VAF 46/184 reads (25%) | catalogued as rs781613659; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500807 T>A | 5'Flank (SNP) | VAF 201/1275 reads (16%) | catalogued as rs764830760; called by muse, mutect2, varscan2
- DCHS2 | n.7345C>G | RNA (SNP) | VAF 68/432 reads (16%) | called by muse, mutect2, varscan2
- DNAJC5 | c.493+113G>T | Intron (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- EXOG | c.163+308_163+310del | Intron (DEL) | VAF 34/224 reads (15%) | catalogued as rs1295091488; called by pindel, varscan2
- FBXO30 | chr6:145791535 del G | 3'Flank (DEL) | VAF 25/182 reads (14%) | called by mutect2, pindel, varscan2
- FMR1 | c.*1248del | 3'UTR (DEL) | VAF 62/324 reads (19%) | catalogued as rs57443689; called by mutect2, varscan2
- HTR1A | c.-23C>A | 5'UTR (SNP) | VAF 23/149 reads (15%) | catalogued as rs201776655; called by muse, mutect2, varscan2
- NCDN | chr1:35557666 T>G | 5'Flank (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- NCSTN | c.*10C>T | 3'UTR (SNP) | VAF 174/465 reads (37%) | called by muse, mutect2, varscan2
- PPIB | chr15:64151730 T>A | 3'Flank (SNP) | VAF 10/43 reads (23%) | called by mutect2, varscan2
- REG3A | c.*6G>T | 3'UTR (SNP) | VAF 37/208 reads (18%) | called by muse, mutect2, varscan2
- SNURFL | n.223C>A | RNA (SNP) | VAF 57/142 reads (40%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2806C>T | RNA (SNP) | VAF 34/262 reads (13%) | called by muse, mutect2, varscan2
- TCEANC2 | c.*8223C>T | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- Unknown | chr21:16071247 G>T | IGR (SNP) | VAF 37/206 reads (18%) | called by muse, mutect2, varscan2
- WAC | c.42-47del | Intron (DEL) | VAF 18/103 reads (17%) | catalogued as rs977694462; called by mutect2, pindel, varscan2
